Somatic mutation profile of tumor specimen TCGA-B3-8121-01A (aliquot TCGA-B3-8121-01A-21D-2396-08) from TCGA case TCGA-B3-8121, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 48.6 years (17,760 days).
Specimen TCGA-B3-8121-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb5276e6-5543-46f8-bdea-f7a02eb26221.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B3-8121-10A (Blood Derived Normal), aliquot TCGA-B3-8121-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e66fca37-06c6-4194-84b2-c607ba9558e7

The open-access MAF lists 37 somatic variants for this specimen: 29 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 19, Silent 8, Frame Shift Del 5, Nonsense Mutation 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.1971C>G p.S657R | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.368); catalogued as rs753772701, COSV56982374, COSV99939873; called by muse, mutect2, varscan2
- ANKRD27 | c.890C>T p.S297F | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs866062215, COSV60129764; called by muse, mutect2, varscan2
- ATP5F1A | c.260T>C p.L87P | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56359781; called by muse, mutect2, varscan2
- ATP5PB | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201457142; called by muse, mutect2, varscan2
- C17orf80 | c.126T>G p.Y42* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV52145447; called by muse, mutect2
- FRMPD2 | c.3913T>C p.S1305P | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV100564032; called by mutect2, varscan2
- H4C2 | c.10C>G p.R4G | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.139); catalogued as COSV55138005, COSV55138490; called by muse, mutect2, varscan2
- KCNQ5 | c.2788A>G p.K930E | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.078); catalogued as COSV59653561; called by muse, mutect2, varscan2
- KLHL14 | c.421T>G p.Y141D | Missense Mutation (SNP) | VAF 49/252 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63831530; called by muse, mutect2, varscan2
- LILRA5 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs748068909, COSV56641994; called by muse, mutect2, varscan2
- NLRC4 | c.1627C>G p.Q543E | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.031); catalogued as COSV61591817; called by muse, mutect2, varscan2
- PKHD1 | c.1139T>G p.F380C | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61865874; called by muse, varscan2
- PTH1R | c.1375T>C p.Y459H | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57314843; called by muse, mutect2
- RAN | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV54562305; called by muse, mutect2, varscan2
- RARS2 | c.978T>A p.D326E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65760457; called by muse, mutect2, varscan2
- SLC16A1 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as COSV63708859; called by muse, mutect2, varscan2
- SNAPIN | c.256C>G p.L86V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV62627071; called by muse, mutect2, varscan2
- TJP1 | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62040338; called by muse, mutect2, varscan2
- TRAV20 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.52); PolyPhen benign (0.43); catalogued as rs780892897; called by muse, mutect2, varscan2
- VCAN | c.9716G>A p.W3239* | Nonsense Mutation (SNP) | VAF 9/65 reads (14%) | catalogued as COSV54099874, COSV54113450, COSV99424268; called by muse, mutect2, varscan2
- ZDHHC11 | c.818T>G p.I273S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.406); catalogued as COSV52064624; called by muse, mutect2, varscan2
- ZNF142 | c.2007G>T p.K669N (on ENST00000411696 / NM_001379660.1; = p.K469N on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV68743233; called by muse, mutect2, varscan2
- CYP51A1 | c.830_837delinsT p.R277Lfs*14 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by pindel, varscan2*
- GIT2 | c.1575_1581del p.Y525* (on ENST00000355312 / NM_057169.5; = p.Y477* on NM_014776.5) | Frame Shift Del (DEL) | VAF 19/109 reads (17%) | called by mutect2, pindel, varscan2
- NUP50 | c.675del p.F225Lfs*40 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- RIOX2 | c.745del p.A249Pfs*6 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel*, varscan2
- S100PBP | c.414del p.L139* | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | called by mutect2, pindel, varscan2
- TRIP6 | c.145dup p.L49Pfs*4 | Frame Shift Ins (INS) | VAF 70/311 reads (23%) | called by mutect2, pindel, varscan2
- ZNF341 | c.849dup p.S284Qfs*11 | Frame Shift Ins (INS) | VAF 109/412 reads (26%) | called by mutect2, pindel, varscan2
- C10orf71 | c.1443G>A p.K481= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- EFCAB3 | c.822T>C p.H274= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as rs1438795117, COSV59500617; called by muse, mutect2, varscan2
- HUWE1 | c.7236G>A p.E2412= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV53338637, COSV53342695; called by muse, mutect2, varscan2
- NLRC4 | c.1626G>A p.E542= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs775705370, COSV61591821; called by muse, mutect2, varscan2
- POMT2 | c.936C>T p.D312= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs186690580; called by muse, mutect2
- RNF13 | c.1095C>T p.V365= | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as COSV53523019; called by muse, mutect2, varscan2
- SLC20A1 | c.1773G>A p.L591= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs763043852, COSV55610569; called by muse, mutect2
- TJP1 | c.4197T>C p.S1399= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV62040329; called by muse, mutect2, varscan2
